CCDI case PBCNUR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/bf08194f-6f92-442b-8376-48887c545d5a

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Myxoid chondrosarcoma: ICD-O-3 morphology code: 9231/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 25.0 years (9,117 days).

Biospecimens (3 samples)
- Sample 0DWD1O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWD23: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWD2B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
